Somatic mutation profile of tumor specimen 0DSPLT from CCDI case PBCFZB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Papillary carcinoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 16.6 years (6,062 days).
Specimen 0DSPLT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7dc1fcfe-90f0-4d31-a556-5e9a9c53ae52.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSPLY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/118e77a7-362c-4187-9ff3-96dfb79bf1e9

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP3M1 | c.80C>A p.S27Y | Missense Mutation (SNP) | VAF 14/340 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- LCT | c.3859G>C p.D1287H | Missense Mutation (SNP) | VAF 16/448 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.863); called by muse, mutect2
- SMC4 | c.3014A>G p.H1005R | Missense Mutation (SNP) | VAF 129/432 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- HERC1 | c.13689-48A>T | Intron (SNP) | VAF 10/82 reads (12%) | called by muse, varscan2
- TCF7 | c.1149-511G>A | Intron (SNP) | VAF 67/203 reads (33%) | called by muse, mutect2, varscan2
